Somatic mutation profile of tumor specimen TCGA-EK-A2R8-01A (aliquot TCGA-EK-A2R8-01A-21D-A18J-09) from TCGA case TCGA-EK-A2R8, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G3; Age at diagnosis: 48.4 years (17,692 days).
Specimen TCGA-EK-A2R8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d59582c1-e570-4732-a666-bcd5bc1e17f9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EK-A2R8-10A (Blood Derived Normal), aliquot TCGA-EK-A2R8-10A-01D-A18J-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a9e4cff-6eb1-4789-bda0-02132e952b77

The open-access MAF lists 321 somatic variants for this specimen: 228 protein-altering or splice-affecting, 89 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 201, Silent 89, Nonsense Mutation 20, 5'Flank 3, Splice Region 3, Frame Shift Del 2, In Frame Del 1, Translation Start Site 1, IGR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLF5 | c.1255G>A p.E419K | Missense Mutation (SNP) | VAF 10/29 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66613960, COSV66613967; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 15/49 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- STK11 | c.536C>A p.P179Q | Missense Mutation (SNP) | VAF 30/62 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58822445, COSV58825728, COSV58829155; called by muse, mutect2, varscan2
- ABCB4 | c.3643G>A p.E1215K (on ENST00000265723 / NM_018849.3; = p.E1208K on NM_000443.4) | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as COSV55934084; called by muse, mutect2, varscan2
- ABCC3 | c.897C>G p.F299L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.407); catalogued as COSV53319711; called by muse, mutect2, varscan2
- ABCC3 | c.996C>G p.L332= | Splice Region (SNP) | VAF 13/48 reads (27%) | catalogued as COSV53319727; called by muse, mutect2
- AC126283.2 | c.893C>T p.S298F | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.022); catalogued as rs780104563, CD057022, COSV67098272; called by muse, varscan2
- ACTR1A | c.655G>C p.E219Q | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV64023141; called by muse, mutect2, varscan2
- ADAM7 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 18/48 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV51538188; called by muse, mutect2, varscan2
- ADAMTSL1 | c.340G>A p.D114N | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV52813542; called by muse, mutect2, varscan2
- ADGRF4 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as COSV51951409; called by muse, mutect2, varscan2
- ADGRG1 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.556); catalogued as COSV65635456; called by muse, varscan2
- ADGRG2 | c.1766G>A p.C589Y (on ENST00000379869 / NM_001079858.3; = p.C586Y on NM_005756.4) | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433616928, COSV61338469; called by muse, mutect2, varscan2
- ADGRL2 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs865853749, COSV54662608; called by muse, mutect2, varscan2
- ADGRV1 | c.2747T>C p.V916A | Missense Mutation (SNP) | VAF 67/113 reads (59%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV67983009; called by muse, mutect2, varscan2
- AGXT | c.236C>G p.S79C | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV56753646; called by muse, mutect2
- AK3 | c.53C>G p.S18W | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773321603, COSV63346554; called by muse, mutect2, varscan2
- ALDH2 | c.988G>A p.D330N | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV55666335; called by muse, mutect2, varscan2
- ALPK2 | c.3982C>G p.L1328V | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0.388); catalogued as COSV100864282, COSV64491985; called by muse, mutect2, varscan2
- AMBRA1 | c.2207C>G p.S736* (on ENST00000458649 / NM_001367468.1; = p.S646* on NM_017749.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 42/100 reads (42%) | catalogued as COSV54051936; called by muse, mutect2, varscan2
- APAF1 | c.287C>T p.S96F | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.6); PolyPhen possibly damaging (0.639); catalogued as rs150823984; called by muse, mutect2, varscan2
- APH1A | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV52528642; called by muse, mutect2, varscan2
- APOH | c.455C>T p.T152I | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV52772102; called by muse, mutect2, varscan2
- ARHGAP4 | c.1575G>C p.E525D | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV61685801, COSV61686030; called by muse, mutect2, varscan2
- ASB2 | c.1078G>A p.E360K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.476); catalogued as COSV60111304; called by muse, mutect2, varscan2
- ASH1L | c.3814C>T p.R1272W | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs750816124, COSV64206961; called by muse, mutect2, varscan2
- ATF4 | c.430C>G p.L144V | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.275); catalogued as COSV57478444; called by muse, mutect2, varscan2
- ATF5 | c.577C>G p.Q193E | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV61311788; called by muse, mutect2, varscan2
- BCOR | c.366G>A p.M122I | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV60704907; called by muse, mutect2, varscan2
- BRD7 | c.1893G>C p.L631F | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV54265812; called by muse, mutect2, varscan2
- C10orf88 | c.1280C>G p.T427S | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV64403857; called by muse, mutect2, varscan2
- C11orf42 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.991); catalogued as COSV56410677; called by muse, mutect2, varscan2
- C2CD3 | c.619C>G p.Q207E | Missense Mutation (SNP) | VAF 53/134 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as COSV58092009; called by muse, mutect2, varscan2
- CACNA1I | c.3981C>G p.L1327= | Splice Region (SNP) | VAF 23/61 reads (38%) | catalogued as COSV60805297, COSV60818417; called by muse, mutect2, varscan2
- CAMSAP2 | c.4379C>G p.S1460C (on ENST00000236925 / NM_001297707.2; = p.S1449C on NM_203459.3) | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52669240; called by muse, mutect2, varscan2
- CAPN3 | c.1024G>C p.D342H | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as COSV58820951; called by muse, mutect2, varscan2
- CCR4 | c.102C>G p.I34M | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV58381952; called by muse, mutect2, varscan2
- CD1A | c.906C>G p.F302L | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56861264; called by muse, mutect2, varscan2
- CD40 | c.645C>T p.I215= | Splice Region (SNP) | VAF 15/62 reads (24%) | catalogued as COSV64847670; called by muse, mutect2, varscan2
- CENPJ | c.3551A>G p.D1184G | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV55038064; called by muse, mutect2
- CHI3L1 | c.397G>C p.D133H | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55137729; called by muse, mutect2, varscan2
- CHL1 | c.2170C>G p.Q724E (on ENST00000397491 / NM_001253387.1; = p.Q740E on NM_006614.4) | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV56590691; called by muse, mutect2, varscan2
- CILK1 | c.105G>A p.M35I | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV63153918; called by muse, mutect2, varscan2
- CLDN2 | c.306G>C p.M102I | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV61020658, COSV61020743; called by muse, mutect2, varscan2
- CNTRL | c.4336G>A p.E1446K | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs772531958, COSV53043071; called by muse, mutect2, varscan2
- COA4 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60155077; called by muse, mutect2, varscan2
- COIL | c.984G>C p.L328F | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV53594570; called by muse, mutect2, varscan2
- COIL | c.373G>C p.D125H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as COSV53594577; called by muse, mutect2, varscan2
- COL11A2 | c.1066G>C p.E356Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.624); catalogued as COSV59495639; called by muse, mutect2, varscan2
- COL13A1 | c.2051G>C p.R684T (on ENST00000398978 / NM_001130103.2; = p.R612T on NM_080798.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV62568618; called by muse, mutect2, varscan2
- CPQ | c.563C>T p.T188M | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.018); catalogued as rs757303134, COSV55137584; called by muse, mutect2, varscan2
- CRB1 | c.107C>G p.S36* | Nonsense Mutation (SNP) | VAF 12/40 reads (30%) | catalogued as CM100225, COSV66339123; called by muse, mutect2, varscan2
- CSE1L | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV53701177; called by muse, mutect2, varscan2
- CSTF2 | c.1097G>T p.G366V | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1457578270, COSV65893708; called by muse, mutect2, varscan2
- CTC1 | c.2380C>A p.Q794K | Missense Mutation (SNP) | VAF 11/30 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV59852864; called by muse, mutect2, varscan2
- CXCR6 | c.891G>C p.K297N | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as rs777650347, COSV56115207; called by muse, mutect2, varscan2
- DAB2 | c.1169C>G p.S390C | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV57913655; called by muse, mutect2, varscan2
- DDX53 | c.988T>C p.Y330H | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60068821; called by muse, mutect2, varscan2
- DENND2B | c.3188C>T p.S1063F | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58202733; called by muse, mutect2, varscan2
- DGAT2 | c.103G>C p.E35Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0.018); catalogued as COSV57175927, COSV57177796; called by muse, mutect2, varscan2
- DGLUCY | c.1531G>A p.D511N | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.472); catalogued as COSV56365563; called by muse, mutect2, varscan2
- DNAJC4 | c.699G>T p.E233D | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.031); catalogued as COSV54172986; called by muse, mutect2, varscan2
- DPY19L3 | c.2045G>A p.R682H | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60475660, COSV60479421; called by muse, mutect2, varscan2
- DSCAML1 | c.3809C>A p.S1270Y (on ENST00000321322; = p.S1210Y on NM_020693.4) | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV58387537; called by muse, mutect2, varscan2
- DSG1 | c.2008C>G p.Q670E | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.288); catalogued as COSV57134483; called by muse, mutect2, varscan2
- DST | c.5985G>T p.M1995I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV55008025; called by muse, varscan2
- EEF2K | c.379G>C p.D127H | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV53780475; called by muse, mutect2, varscan2
- EP300 | c.1681C>T p.Q561* | Nonsense Mutation (SNP) | VAF 18/58 reads (31%) | catalogued as COSV54330509; called by muse, mutect2, varscan2
- FAM184A | c.868G>C p.E290Q | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as rs1431503660, COSV58853284, COSV58859010; called by muse, mutect2, varscan2
- FBN2 | c.6237C>G p.F2079L | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV52506269; called by muse, mutect2, varscan2
- FBXL19 | c.1583C>T p.S528L | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV100609356; called by muse, mutect2, varscan2
- FBXO22 | c.496C>T p.Q166* | Nonsense Mutation (SNP) | VAF 17/59 reads (29%) | catalogued as COSV57617150; called by muse, mutect2, varscan2
- FCHSD2 | c.2068C>T p.H690Y | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.027); catalogued as COSV60808315; called by muse, mutect2, varscan2
- FGF8 | c.187C>T p.Q63* (on ENST00000344255 / NM_033164.4; = p.Q45* on NM_006119.6) | Nonsense Mutation (SNP) | VAF 19/80 reads (24%) | catalogued as COSV60142121, COSV60142701; called by muse, mutect2, varscan2
- FJX1 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs1353457587; called by muse, mutect2
- FLII | c.2518G>A p.D840N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.975); catalogued as rs1434461837, COSV57497402; called by muse, mutect2, varscan2
- FNBP1 | c.1405C>T p.R469* | Nonsense Mutation (SNP) | VAF 13/46 reads (28%) | catalogued as rs1242601997, COSV63086397; called by muse, mutect2, varscan2
- FO393400.1 | c.295C>G p.L99V | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV54069950; called by muse, mutect2, varscan2
- FRA10AC1 | c.387G>T p.K129N | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV63271419; called by muse, mutect2, varscan2
- FUCA2 | c.433G>C p.E145Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as COSV50019973; called by muse, mutect2, varscan2
- FYN | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57612874, COSV57613695; called by muse, mutect2, varscan2
- GAD1 | c.38C>G p.S13W | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.257); catalogued as COSV60152019, COSV60154339; called by muse, mutect2, varscan2
- GBA2 | c.304C>G p.Q102E | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV65239245, COSV65239933; called by muse, mutect2, varscan2
- GDA | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as COSV52990381, COSV52995383; called by muse, mutect2, varscan2
- GNA15 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1396214838, COSV53585766; called by muse, mutect2, varscan2
- GPRASP1 | c.2512G>C p.E838Q | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.917); catalogued as COSV64355335; called by muse, mutect2, varscan2
- GRIK4 | c.1948G>C p.D650H | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV70801504; called by muse, mutect2, varscan2
- GRK5 | c.913G>C p.E305Q | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); catalogued as COSV64866125; called by muse, mutect2, varscan2
- GUSB | c.1190A>G p.D397G | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV59221405; called by muse, mutect2, varscan2
- HAP1 | c.1147G>A p.E383K | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV57878083; called by muse, mutect2, varscan2
- HAUS6 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 8/30 reads (27%) | catalogued as COSV65839808; called by muse, mutect2, varscan2
- HCN2 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 55/100 reads (55%) | SIFT tolerated (0.64); PolyPhen benign (0.018); catalogued as rs1262524303, COSV52113828; called by muse, mutect2, varscan2
- HECTD4 | c.11084G>A p.R3695K | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV66389939; called by muse, mutect2, varscan2
- HEY2 | c.6G>C p.K2N | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1364746682, COSV64239657; called by muse, mutect2, varscan2
- HFM1 | c.4154C>T p.S1385F | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.564); catalogued as COSV54025309, COSV99646334; called by muse, mutect2, varscan2
- HOXB6 | c.422C>T p.S141F | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.093); catalogued as COSV53312447; called by muse, mutect2, varscan2
- HOXC8 | c.423G>A p.W141* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | catalogued as COSV50000948; called by muse, mutect2, varscan2
- HRNR | c.1376C>G p.S459* | Nonsense Mutation (SNP) | VAF 53/148 reads (36%) | catalogued as COSV64253971; called by muse, mutect2, varscan2
- HSPA8 | c.1936G>C p.D646H | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.969); catalogued as COSV57083572; called by muse, mutect2, varscan2
- INTS2 | c.1780C>G p.P594A | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.987); catalogued as COSV52152533; called by muse, mutect2, varscan2
- KANSL2 | c.511G>A p.D171N | Missense Mutation (SNP) | VAF 33/91 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV63479568; called by muse, mutect2, varscan2
- KCNJ4 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as COSV57856721; called by muse, mutect2, varscan2
- KMT2E | c.5230C>T p.H1744Y | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as COSV57571791; called by muse, mutect2, varscan2
- KRT38 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as rs1403730511, COSV55845758; called by muse, mutect2, varscan2
- KRT81 | c.1370G>A p.C457Y | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.836); catalogued as COSV59809496; called by muse, mutect2, varscan2
- KRT85 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.348); catalogued as rs549707125, COSV57736489; called by muse, mutect2, varscan2
- LGI3 | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60443205; called by muse, mutect2, varscan2
- LMTK2 | c.3625C>T p.L1209F | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV51994000; called by muse, mutect2, varscan2
- LONRF3 | c.1272C>A p.C424* (on ENST00000371628 / NM_001031855.3; = p.C383* on NM_024778.5) | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as COSV59151450; called by muse, mutect2, varscan2
- LPIN1 | c.2107C>T p.Q703* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as COSV56764329; called by muse, mutect2, varscan2
- LRP4 | c.4227C>G p.I1409M | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66135202; called by muse, mutect2, varscan2
- LRRC37B | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 55/205 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV58951798; called by muse, mutect2, varscan2
- MACF1 | c.19224G>C p.K6408N (on ENST00000372915; = p.K4453N on NM_012090.5) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | catalogued as rs1431257492, COSV57116471; called by muse, mutect2, varscan2
- MAP7D1 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.057); catalogued as rs552661941, COSV60215812; called by muse, mutect2, varscan2
- MARCHF4 | c.338C>T p.S113F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.154); catalogued as rs1402194198, COSV56104335; called by muse, mutect2
- MED15 | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs763744861, COSV53026625; called by muse, mutect2, varscan2
- MEP1A | c.2208C>G p.I736M | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV57919352; called by muse, mutect2, varscan2
- MROH7 | c.260G>C p.R87T | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as COSV59870480; called by muse, mutect2, varscan2
- MYH2 | c.1851G>A p.M617I | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV55435486; called by muse, mutect2, varscan2
- MYO18B | c.7554C>G p.F2518L | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.121); catalogued as COSV100125037; called by muse, mutect2, varscan2
- MYO5A | c.979C>T p.R327* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as COSV62558771; called by muse, mutect2, varscan2
- MYOM1 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as COSV55289468; called by muse, mutect2
- NAA60 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 33/96 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.827); catalogued as COSV62654566; called by muse, mutect2, varscan2
- NASP | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.852); catalogued as rs759202853, COSV63112633; called by muse, mutect2, varscan2
- NAV2 | c.4196C>T p.S1399L (on ENST00000396087 / NM_001244963.2; = p.S1376L on NM_145117.5) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); catalogued as rs745496755, COSV60658292; called by muse, varscan2
- NAV2 | c.4273C>T p.Q1425* (on ENST00000396087 / NM_001244963.2; = p.Q1402* on NM_145117.5) | Nonsense Mutation (SNP) | VAF 9/41 reads (22%) | catalogued as COSV60658300; called by muse, varscan2
- NDST2 | c.244C>T p.R82* | Nonsense Mutation (SNP) | VAF 11/46 reads (24%) | catalogued as rs753508212, COSV55213779; called by muse, mutect2, varscan2
- NEURL4 | c.2092G>A p.E698K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.145); catalogued as rs186968090, COSV100223294; called by muse, mutect2, varscan2
- NFATC4 | c.365C>G p.S122C | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as COSV51599827; called by muse, mutect2
- NFYA | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.031); catalogued as rs1400950091, COSV58198280; called by muse, mutect2, varscan2
- NHS | c.3913C>T p.Q1305* | Nonsense Mutation (SNP) | VAF 15/41 reads (37%) | catalogued as COSV66273597, COSV66281407; called by muse, mutect2, varscan2
- NISCH | c.3460G>C p.E1154Q | Missense Mutation (SNP) | VAF 31/101 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV61899368; called by muse, mutect2, varscan2
- NLRP7 | c.217A>G p.N73D | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.029); catalogued as COSV60172898; called by muse, mutect2, varscan2
- NPAS4 | c.480G>C p.Q160H | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1245038681, COSV60649843, COSV60652063; called by muse, mutect2, varscan2
- NRDC | c.2728G>C p.E910Q | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.173); catalogued as COSV61403466; called by muse, mutect2, varscan2
- NSMAF | c.284G>C p.R95T | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV50685598; called by muse, mutect2, varscan2
- NSMF | c.831G>C p.Q277H (on ENST00000371475 / NM_001130969.3; = p.Q275H on NM_015537.4) | Missense Mutation (SNP) | VAF 21/101 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV55810461; called by muse, mutect2, varscan2
- NSUN4 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as rs1236165356, COSV61062914; called by muse, mutect2, varscan2
- OBSCN | c.19160C>T p.S6387L | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs371696980, COSV52771546; called by muse, mutect2, varscan2
- OTUD7A | c.907G>C p.E303Q (on ENST00000307050 / NM_001382637.1; = p.E296Q on NM_130901.3) | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs147009957; called by muse, mutect2, varscan2
- PAK6 | c.1606C>T p.L536F | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.975); catalogued as rs544478594, COSV53045092; called by muse, mutect2, varscan2
- PAPOLA | c.1259C>G p.S420* | Nonsense Mutation (SNP) | VAF 20/60 reads (33%) | catalogued as COSV53478884; called by muse, mutect2, varscan2
- PCDHB11 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 55/88 reads (63%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV61310837; called by muse, mutect2, varscan2
- PCDHB14 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 116/172 reads (67%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.056); catalogued as rs782444503, COSV53387769; called by muse, mutect2, varscan2
- PDE10A | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV63094477; called by muse, mutect2, varscan2
- PDZK1 | c.1532C>T p.S511F | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs781910973, COSV58258974; called by muse, mutect2, varscan2
- PEX6 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV55102622; called by muse, mutect2, varscan2
- PI4KA | c.892G>C p.E298Q | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV55408568; called by muse, mutect2
- PIGU | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.849); catalogued as rs759108515, COSV54161720; called by muse, mutect2, varscan2
- PKD1 | c.10879G>C p.D3627H (on ENST00000262304 / NM_001009944.3; = p.D3626H on NM_000296.4) | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51913957; called by muse, mutect2, varscan2
- PLEKHG1 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs757089123, COSV62046530; called by muse, mutect2, varscan2
- PLEKHG4B | c.1072G>C p.E358Q (on ENST00000283426; = p.E714Q on NM_052909.5) | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.255); catalogued as COSV52045995, COSV52050761; called by muse, mutect2, varscan2
- PNLIPRP1 | c.809G>C p.W270S | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.915); catalogued as COSV100724467, COSV62611398; called by muse, mutect2, varscan2
- PRPF18 | c.381G>C p.L127F | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV60724984; called by muse, mutect2, varscan2
- PSIP1 | c.262C>T p.P88S | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as COSV66254260; called by muse, mutect2, varscan2
- PTPRB | c.3367G>C p.D1123H | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1327501942, COSV54238260, COSV54248666; called by muse, mutect2, varscan2
- PUS10 | c.169G>C p.D57H | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.24); catalogued as COSV57451521; called by muse, mutect2, varscan2
- PXDNL | c.3491C>T p.S1164L | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.439); catalogued as COSV100686011; called by muse, mutect2, varscan2
- RAD23B | c.1016G>C p.G339A | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.267); catalogued as COSV63658086; called by muse, mutect2, varscan2
- RADIL | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 10/31 reads (32%) | catalogued as rs768636132, COSV68200206; called by muse, mutect2, varscan2
- RALGAPA1 | c.3085C>T p.L1029F | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.854); catalogued as COSV51880431; called by muse, mutect2, varscan2
- RASD1 | c.44C>G p.S15W | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs752476220, COSV51957302; called by muse, mutect2, varscan2
- RMDN2 | c.745G>A p.E249K (on ENST00000354545 / NM_001322212.2; = p.E427K on NM_144713.5) | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.702); catalogued as COSV52223983; called by muse, mutect2, varscan2
- RMND5B | c.658C>T p.R220W | Missense Mutation (SNP) | VAF 59/89 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1007932088, COSV57744262; called by muse, mutect2, varscan2
- ROR1 | c.2403G>C p.Q801H | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV64286155; called by muse, mutect2, varscan2
- SBNO1 | c.1223G>C p.S408T (on ENST00000420886; = p.S407T on NM_018183.5) | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV57340575; called by muse, mutect2, varscan2
- SBNO2 | c.312C>G p.I104M | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.037); catalogued as COSV62319777; called by muse, mutect2, varscan2
- SEZ6L2 | c.707G>A p.G236E (on ENST00000308713 / NM_001114099.3; = p.G166E on NM_012410.4) | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.941); catalogued as rs1458457613, COSV58098637, COSV58100989, COSV58104211; called by muse, mutect2, varscan2
- SHF | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as COSV52050073; called by muse, mutect2, varscan2
- SHOC2 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as COSV54620933; called by muse, mutect2, varscan2
- SLC26A11 | c.1400C>G p.S467C | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); catalogued as COSV63279241; called by muse, mutect2, varscan2
- SLC26A3 | c.146A>G p.K49R | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.76); PolyPhen benign (0.006); catalogued as COSV60639786; called by muse, mutect2, varscan2
- SLC27A2 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51058350; called by muse, mutect2, varscan2
- SLC44A3 | c.1451G>A p.C484Y (on ENST00000271227 / NM_001114106.3; = p.C436Y on NM_152369.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV54729329; called by muse, mutect2, varscan2
- SLC50A1 | c.414C>G p.I138M | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.672); catalogued as COSV100310496; called by muse, mutect2, varscan2
- SLC9C2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as rs1367001947, COSV100876675; called by muse, mutect2, varscan2
- SMAP1 | c.14C>G p.S5C | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV57637507; called by muse, mutect2, varscan2
- SORL1 | c.901C>G p.Q301E | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.965); catalogued as COSV52752409; called by muse, mutect2, varscan2
- SPAG17 | c.4459C>A p.Q1487K | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.146); catalogued as COSV60456478; called by muse, mutect2, varscan2
- SPAG5 | c.3484G>C p.D1162H | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56885889; called by muse, mutect2, varscan2
- SPAG5 | c.1532C>G p.S511C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); catalogued as COSV58801213; called by muse, mutect2, varscan2
- SPAG5 | c.1172C>T p.S391L | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.069); catalogued as COSV58801220; called by muse, mutect2, varscan2
- SPAG5 | c.329C>G p.S110C | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.971); catalogued as COSV58801228; called by muse, mutect2, varscan2
- SPATA31D1 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV61194547; called by muse, mutect2, varscan2
- SPTBN5 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58019194; called by muse, mutect2, varscan2
- SRSF5 | c.350C>G p.S117* | Nonsense Mutation (SNP) | VAF 9/30 reads (30%) | catalogued as COSV67936649; called by muse, mutect2, varscan2
- SUCLA2 | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV66222146; called by muse, mutect2, varscan2
- TANC2 | c.419C>G p.S140C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV67333028; called by muse, mutect2, varscan2
- TAOK2 | c.2698G>C p.E900Q | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.122); catalogued as COSV54234770; called by muse, mutect2, varscan2
- TARS2 | c.1891G>C p.E631Q | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.04); catalogued as COSV60872491; called by muse, mutect2, varscan2
- TBC1D8 | c.2163G>C p.L721F | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.03); catalogued as COSV65211444; called by muse, mutect2, varscan2
- TCF7L1 | c.606C>G p.F202L | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV56397668; called by muse, mutect2, varscan2
- TMC1 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52769278; called by muse, mutect2, varscan2
- TMEM131 | c.1850C>T p.S617L | Missense Mutation (SNP) | VAF 5/59 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1160873864, COSV99489448; called by muse, mutect2
- TMEM241 | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV67243616; called by muse, mutect2, varscan2
- TMEM52 | c.486G>C p.K162N | Missense Mutation (SNP) | VAF 26/71 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV57069113; called by muse, mutect2, varscan2
- TNFRSF10A | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.541); catalogued as COSV55325402; called by muse, mutect2, varscan2
- TNIP3 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as COSV50246894; called by muse, mutect2, varscan2
- TNRC6B | c.4298C>T p.P1433L (on ENST00000454349 / NM_001162501.2; = p.P1323L on NM_015088.3) | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57292919; called by muse, mutect2, varscan2
- TRAF3IP1 | c.1795C>T p.P599S | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); catalogued as COSV64852424; called by muse, mutect2, varscan2
- TRIM65 | c.607G>A p.E203K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs199545843; called by muse, mutect2, varscan2
- TRUB2 | c.865C>T p.Q289* | Nonsense Mutation (SNP) | VAF 17/41 reads (41%) | catalogued as COSV65759112, COSV65759474; called by muse, mutect2, varscan2
- TTC36 | c.133C>G p.Q45E | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57096076; called by muse, mutect2, varscan2
- TTLL7 | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs775482319, COSV53083252; called by muse, mutect2, varscan2
- UBR2 | c.4873G>C p.D1625H | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV65749698; called by muse, mutect2, varscan2
- UBXN10 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV66771981; called by muse, mutect2, varscan2
- UNC45B | c.203G>C p.R68T | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.009); catalogued as COSV52094203, COSV99269062; called by muse, mutect2, varscan2
- VEGFC | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as rs752936139, COSV54596369; called by muse, mutect2, varscan2
- VEPH1 | c.625C>G p.Q209E | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV62877899; called by muse, mutect2, varscan2
- VPS13A | c.4226G>A p.S1409N | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.71); PolyPhen possibly damaging (0.859); catalogued as COSV62427769, COSV62428727, COSV62432653; called by muse, mutect2, varscan2
- VSX1 | c.427G>C p.E143Q | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV65021536; called by muse, mutect2, varscan2
- WSCD2 | c.1240G>A p.A414T | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as rs761428246, COSV54578076, COSV99775082; called by muse, mutect2, varscan2
- YBEY | c.247C>G p.P83A | Missense Mutation (SNP) | VAF 35/53 reads (66%) | SIFT tolerated (0.4); PolyPhen benign (0.018); catalogued as COSV59309755, COSV59311255; called by muse, mutect2, varscan2
- YY2 | c.656T>A p.L219H | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV63411140; called by muse, mutect2, varscan2
- ZNF154 | c.135G>C p.E45D | Missense Mutation (SNP) | VAF 41/101 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.049); catalogued as COSV101377479, COSV70744905; called by muse, mutect2, varscan2
- ZNF341 | c.1485G>C p.K495N (on ENST00000375200 / NM_001282935.1; = p.K488N on NM_032819.4) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as COSV61007737; called by muse, mutect2, varscan2
- ZNF404 | c.283G>A p.E95K | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as COSV60986919; called by muse, mutect2, varscan2
- ZNF483 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV58515237; called by muse, mutect2, varscan2
- ZNF521 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.04); catalogued as rs1472629434, COSV64125218; called by muse, mutect2, varscan2
- ZNF8 | c.424G>C p.E142Q | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.01); catalogued as COSV52187222, COSV52188235; called by muse, mutect2, varscan2
- ZSWIM1 | c.1299G>C p.W433C | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.556); catalogued as COSV54846643; called by muse, mutect2, varscan2
- ACACA | c.6832G>C p.D2278H | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated (0.53); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ADHFE1 | c.130_134del p.D44Cfs*3 | Frame Shift Del (DEL) | VAF 7/29 reads (24%) | called by mutect2, pindel, varscan2
- CFAP74 | c.4150G>A p.D1384N | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- GAS2L2 | c.2183C>G p.S728W | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2, varscan2
- SPATA31A1 | c.3013C>G p.L1005V | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- USP35 | c.2896_2898del p.E966del | In Frame Del (DEL) | VAF 13/41 reads (32%) | called by mutect2, pindel, varscan2
- WWC3 | c.1522del p.D508Tfs*38 | Frame Shift Del (DEL) | VAF 4/23 reads (17%) | called by pindel, varscan2
- ADCY9 | c.1491C>T p.C497= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as rs759050637, COSV53574048; called by muse, mutect2, varscan2
- ADGRG1 | c.738C>G p.L246= | Silent (SNP) | VAF 18/64 reads (28%) | catalogued as COSV101113552; called by muse, varscan2
- ARHGAP1 | c.411C>A p.L137= | Silent (SNP) | VAF 23/90 reads (26%) | catalogued as COSV61734740; called by muse, mutect2, varscan2
- ARHGDIA | c.75C>G p.V25= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as COSV53906603; called by muse, mutect2, varscan2
- ARHGEF10 | c.2949G>A p.V983= (on ENST00000398564; = p.V958= on NM_014629.4) | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV100035560, COSV50645838; called by muse, mutect2, varscan2
- BPIFB2 | c.1263C>G p.L421= | Silent (SNP) | VAF 37/88 reads (42%) | catalogued as COSV50063919, COSV50068242; called by muse, mutect2, varscan2
- CELF2 | c.558G>A p.Q186= (on ENST00000416382 / NM_001025077.3; = p.Q193= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 48/161 reads (30%) | catalogued as COSV59969017, COSV59970162; called by muse, mutect2, varscan2
- CEP128 | c.2100C>G p.L700= | Silent (SNP) | VAF 34/102 reads (33%) | catalogued as COSV99825896; called by muse, mutect2, varscan2
- CRYGD | c.354C>T p.F118= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV52205053; called by muse, mutect2, varscan2
- CUL4B | c.1125G>C p.L375= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV60686509; called by muse, mutect2, varscan2
- DNAH3 | c.3810C>G p.V1270= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as COSV54515066; called by muse, mutect2, varscan2
- EFHD2 | c.342G>A p.L114= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV101044494; called by muse, mutect2, varscan2
- EHD1 | c.621G>A p.L207= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as COSV57734298; called by muse, mutect2, varscan2
- EPB41L3 | c.1590G>A p.R530= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as COSV59449912; called by muse, mutect2, varscan2
- FHOD3 | c.2571C>T p.V857= (on ENST00000359247 / NM_001281739.3; = p.V874= on NM_025135.5) | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV99942768; called by muse, mutect2, varscan2
- GIPR | c.177C>T p.L59= | Silent (SNP) | VAF 17/108 reads (16%) | catalogued as COSV54423208, COSV54423522; called by muse, mutect2, varscan2
- GLRA2 | c.324G>A p.A108= | Silent (SNP) | VAF 31/64 reads (48%) | catalogued as rs199797447, COSV54338643; called by muse, mutect2, varscan2
- GPR101 | c.795G>A p.Q265= | Silent (SNP) | VAF 44/142 reads (31%) | catalogued as COSV53238523; called by muse, mutect2, varscan2
- GUCY2C | c.309C>G p.L103= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV53788936, COSV53793617; called by muse, mutect2, varscan2
- H1-5 | c.594G>A p.P198= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV58898866; called by muse, mutect2, varscan2
- H2AC8 | c.366G>A p.E122= | Silent (SNP) | VAF 40/100 reads (40%) | catalogued as COSV55126469, COSV55126575; called by muse, mutect2, varscan2
- HDLBP | c.3252G>A p.V1084= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as rs1374528491, COSV100191766; called by muse, mutect2, varscan2
- HERPUD1 | c.36C>G p.L12= | Silent (SNP) | VAF 8/24 reads (33%) | catalogued as COSV55861900; called by muse, varscan2
- HIVEP1 | c.3342A>G p.Q1114= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs773724352, COSV65100378; called by muse, mutect2, varscan2
- HOXC9 | c.624G>A p.E208= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs1353503567, COSV57716598; called by muse, mutect2, varscan2
- LRRC37A2 | c.4944C>G p.L1648= | Silent (SNP) | VAF 30/97 reads (31%) | catalogued as COSV60236106; called by muse, mutect2, varscan2
- LRRK1 | c.273G>A p.L91= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as COSV52607646; called by muse, mutect2, varscan2
- MAP2 | c.54G>A p.P18= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs754431951, COSV52280851; ClinVar: likely benign; called by muse, mutect2, varscan2
- MARS1 | c.1653C>T p.F551= | Silent (SNP) | VAF 33/117 reads (28%) | catalogued as COSV56253814; called by muse, mutect2, varscan2
- MBD6 | c.699C>G p.L233= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV63073889; called by muse, mutect2, varscan2
- METTL21A | c.504G>A p.V168= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV55881425; called by muse, mutect2, varscan2
- MFHAS1 | c.471C>T p.L157= | Silent (SNP) | VAF 21/71 reads (30%) | catalogued as rs753135388, COSV52281230; called by muse, mutect2, varscan2
- MTTP | c.2088C>G p.L696= | Silent (SNP) | VAF 41/96 reads (43%) | catalogued as COSV55505092; called by muse, mutect2, varscan2
- MUC16 | c.40917C>T p.L13639= | Silent (SNP) | VAF 35/78 reads (45%) | catalogued as COSV66690762; called by muse, mutect2, varscan2
- MYNN | c.306C>G p.L102= | Silent (SNP) | VAF 20/102 reads (20%) | catalogued as COSV62991137; called by muse, mutect2, varscan2
- MYO9A | c.5307G>A p.K1769= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV100614242; called by muse, mutect2, varscan2
- NOL6 | c.1944G>C p.L648= | Silent (SNP) | VAF 38/149 reads (26%) | catalogued as COSV53040876; called by muse, mutect2, varscan2
- NRIP2 | c.672G>A p.E224= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as COSV57389413; called by muse, mutect2, varscan2
- NSUN3 | c.498G>C p.L166= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV58934838; called by muse, mutect2, varscan2
- NUP205 | c.2028G>A p.V676= | Silent (SNP) | VAF 16/58 reads (28%) | catalogued as COSV53657516; called by muse, mutect2, varscan2
- OR2T34 | c.675C>T p.L225= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as COSV60900059; called by muse, mutect2, varscan2
- OR4F4 | c.846G>T p.L282= | Silent (SNP) | VAF 36/184 reads (20%) | catalogued as COSV58220052; called by muse, mutect2, varscan2
- OR5L1 | c.912G>C p.V304= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as rs1399486603, COSV61733456, COSV61733754; called by muse, mutect2
- PDE4DIP | c.1956G>A p.V652= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as rs782495232, COSV57685765, COSV57689400; called by mutect2, varscan2
- PPP3CB | c.1296C>G p.L432= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV100646013, COSV61151707; called by muse, mutect2, varscan2
- PRPF8 | c.6315C>T p.I2105= | Silent (SNP) | VAF 34/84 reads (40%) | catalogued as COSV56773177; called by muse, mutect2, varscan2
- PRPF8 | c.6030C>T p.I2010= | Silent (SNP) | VAF 32/79 reads (41%) | catalogued as COSV56773184; called by muse, mutect2, varscan2
- PRRC2B | c.5877C>T p.I1959= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as COSV57644880; called by muse, mutect2, varscan2
- PRRC2B | c.6006C>T p.P2002= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as COSV100260839, COSV100261136; called by muse, mutect2, varscan2
- PTPRB | c.519C>T p.L173= | Silent (SNP) | VAF 25/62 reads (40%) | catalogued as COSV54238274; called by muse, mutect2, varscan2
- PTPRS | c.156C>T p.F52= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as rs371714657; called by muse, mutect2, varscan2
- QTRT1 | c.903G>A p.L301= | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as COSV51551086; called by muse, mutect2, varscan2
- RSPH10B | c.1548C>T p.L516= | Silent (SNP) | VAF 12/119 reads (10%) | catalogued as COSV100521428; called by muse, mutect2
- RSPH10B2 | c.1548C>T p.L516= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV51868678, COSV99786208; called by mutect2, varscan2
- SAMD5 | c.414C>A p.L138= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as rs1199841910, COSV100822437, COSV66585137; called by muse, mutect2, varscan2
- SCARF2 | c.279G>C p.V93= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV56731738; called by muse, mutect2, varscan2
- SDC4 | c.519G>A p.K173= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV65595303; called by muse, mutect2
- SEL1L3 | c.724C>T p.L242= | Silent (SNP) | VAF 15/31 reads (48%) | catalogued as rs756390882, COSV53539250; called by muse, mutect2, varscan2
- SIDT1 | c.2364C>T p.F788= | Silent (SNP) | VAF 29/94 reads (31%) | catalogued as rs150661858, COSV53499161; called by muse, mutect2, varscan2
- SIGLEC1 | c.990G>A p.V330= | Silent (SNP) | VAF 15/58 reads (26%) | catalogued as COSV52461653; called by muse, mutect2, varscan2
- SLC16A10 | c.711C>G p.L237= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV100920977; called by muse, mutect2, varscan2
- SLC17A4 | c.735C>G p.L245= | Silent (SNP) | VAF 20/59 reads (34%) | catalogued as COSV100930666, COSV64955654; called by muse, mutect2, varscan2
- SLC1A7 | c.273C>T p.L91= | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as rs776184320, COSV65194936; called by muse, mutect2, varscan2
- SOS1 | c.3006G>A p.E1002= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as rs1335525164, COSV67674545; called by muse, mutect2, varscan2
- SRF | c.969G>A p.L323= | Silent (SNP) | VAF 29/77 reads (38%) | catalogued as COSV54837688, COSV54838287; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.15G>A p.L5= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as COSV60328015; called by muse, mutect2, varscan2
- SYMPK | c.1977G>A p.Q659= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV55610831; called by muse, mutect2, varscan2
- SYNM | c.975C>T p.I325= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as COSV60369429; called by muse, mutect2, varscan2
- TAOK2 | c.1686G>A p.R562= | Silent (SNP) | VAF 13/41 reads (32%) | catalogued as rs765535557, COSV54234742; called by muse, mutect2, varscan2
- TAS1R2 | c.1050C>T p.L350= | Silent (SNP) | VAF 16/57 reads (28%) | catalogued as COSV64744395; called by muse, mutect2, varscan2
- TEX10 | c.2619C>T p.L873= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs191855673, COSV52440462; called by muse, mutect2, varscan2
- TFF1 | c.60C>A p.L20= | Silent (SNP) | VAF 11/20 reads (55%) | catalogued as rs142874600, COSV52298373; called by muse, mutect2, varscan2
- TFRC | c.447A>G p.E149= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV64054415; called by muse, mutect2, varscan2
- TMC3 | c.1665C>T p.F555= | Silent (SNP) | VAF 16/35 reads (46%) | catalogued as COSV63922722; called by muse, mutect2, varscan2
- TMEM225 | c.252G>A p.L84= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs774566780, COSV66693052; called by muse, mutect2, varscan2
- TNFAIP2 | c.1689C>T p.F563= | Silent (SNP) | VAF 24/88 reads (27%) | catalogued as rs1413567424, COSV100281095; called by muse, mutect2, varscan2
- TRBV20-1 | c.285G>A p.V95= | Silent (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- TTF1 | c.111C>T p.F37= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV57503354; called by muse, mutect2, varscan2
- TTN | c.90741A>G p.A30247= (on ENST00000591111; = p.A22823= on NM_003319.4) | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV59984040; called by muse, varscan2
- TUBGCP3 | c.282C>T p.L94= | Silent (SNP) | VAF 8/33 reads (24%) | catalogued as COSV56185913; called by muse, mutect2, varscan2
- TUBGCP6 | c.1725C>G p.L575= | Silent (SNP) | VAF 16/48 reads (33%) | catalogued as COSV50541011; called by muse, mutect2, varscan2
- UBE3C | c.2373C>T p.F791= | Silent (SNP) | VAF 12/20 reads (60%) | catalogued as COSV61952531; called by muse, mutect2, varscan2
- UEVLD | c.1065C>G p.L355= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as rs1428135394, COSV57874009; called by muse, mutect2, varscan2
- UPK1A | c.447C>G p.L149= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as rs767448820, COSV55877909; called by muse, mutect2
- VCAM1 | c.1131C>T p.N377= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as rs372051353; called by muse, mutect2, varscan2
- ZFHX3 | c.8103C>T p.F2701= | Silent (SNP) | VAF 23/60 reads (38%) | catalogued as rs1179003246, COSV51714670; called by muse, mutect2, varscan2
- ZNRF4 | c.642G>T p.V214= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as COSV55773659; called by muse, mutect2, varscan2
- ZSCAN20 | c.2259C>G p.L753= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV63682256; called by muse, mutect2, varscan2
- ZW10 | c.1665C>T p.L555= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as rs146253851; called by muse, mutect2, varscan2
- FUT7 | chr9:137034820 G>C | 5'Flank (SNP) | VAF 8/36 reads (22%) | catalogued as rs1193690084; called by muse, mutect2, varscan2
- FUT7 | chr9:137034962 G>C | 5'Flank (SNP) | VAF 9/30 reads (30%) | called by muse, mutect2, varscan2
- SREK1 | chr5:66144512 G>C | 5'Flank (SNP) | VAF 54/81 reads (67%) | catalogued as rs1033563264, COSV61903819; called by muse, mutect2, varscan2
- Unknown | chr21:16071287 G>A | IGR (SNP) | VAF 14/31 reads (45%) | called by muse, mutect2, varscan2
